Somatic mutation profile of tumor specimen MMRF_2290_1_BM_CD138pos (aliquot MMRF_2290_1_BM_CD138pos_T1_KHS5U_L09546) from MMRF case MMRF_2290, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.4 years (29,009 days).
Specimen MMRF_2290_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e1a2df6-f3fc-47a3-86bd-78824f3d6302.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2290_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2290_1_PB_Whole_C3_KHS5U_L09547; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98757924-d840-4f96-8217-d77f8b3f23ae

The open-access MAF lists 157 somatic variants for this specimen: 65 protein-altering or splice-affecting, 20 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 40, Silent 20, Intron 19, Nonsense Mutation 5, 5'UTR 4, 5'Flank 3, 3'Flank 3, RNA 3, Frame Shift Del 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 48/92 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ADAMTS13 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1554784062; called by muse, mutect2, varscan2
- AMPD3 | c.730C>T p.H244Y (on ENST00000396553 / NM_001025389.2; = p.H253Y on NM_000480.3) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1296626752; called by muse, mutect2
- DMD | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63735623; called by muse, mutect2, varscan2
- DNAH17 | c.11140G>A p.V3714I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); catalogued as rs151093068; called by muse, mutect2, varscan2
- FAM155B | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as COSV52937233; called by muse, mutect2, varscan2
- FGF19 | c.451del p.R151Gfs*59 | Frame Shift Del (DEL) | VAF 60/175 reads (34%) | catalogued as COSV53736953; called by mutect2, pindel, varscan2
- FOXC1 | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs1561674584; called by muse, mutect2, varscan2
- GPKOW | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs372379511, COSV50242086; called by muse, mutect2, varscan2
- GSDMB | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147293765; called by muse, mutect2, varscan2
- HTR1A | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60502630; called by muse, mutect2, varscan2
- HTR1A | c.30C>A p.N10K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as rs1473053420; called by muse, mutect2, varscan2
- IGHJ2 | c.9C>G p.Y3* | Nonsense Mutation (SNP) | VAF 41/41 reads (100%) | catalogued as rs370780867; called by muse, varscan2
- IGHJ3 | c.13A>C p.I5L | Missense Mutation (SNP) | VAF 33/33 reads (100%) | PolyPhen benign (0.003); catalogued as rs190698203; called by muse, mutect2, varscan2
- IGHV2-70 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs557763852; called by muse, varscan2
- IGHV2-70 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs370008108; called by muse, varscan2
- IGHV2-70 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.42); catalogued as rs369999266; called by muse, varscan2
- IGHV2-70 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs367964005; called by muse, varscan2
- INTS8 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58253771; called by muse, mutect2, varscan2
- NRG1 | c.218C>A p.P73Q (on ENST00000523534; = p.P220Q on NM_013962.2) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101584773; called by muse, mutect2, varscan2
- OR2T6 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs758848003, COSV100861532; called by muse, mutect2, varscan2
- OR5AR1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1340121814; called by muse, mutect2, varscan2
- PAPPA | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762475600, COSV100074338; called by muse, mutect2, varscan2
- POLR3E | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs759332570, COSV55401357; called by muse, mutect2, varscan2
- RB1 | c.865A>T p.K289* | Nonsense Mutation (SNP) | VAF 13/13 reads (100%) | catalogued as rs1160807049, CM143225, COSV57301073; called by muse, mutect2, varscan2
- RNF17 | c.4217C>T p.S1406F | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.231); catalogued as COSV55052107; called by muse, mutect2, varscan2
- SDK1 | c.5489G>A p.G1830D | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745305864, COSV67369654; called by muse, mutect2, varscan2
- SHANK2 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs782758703; called by muse, mutect2, varscan2
- TNRC18 | c.5357G>A p.R1786Q | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.384); catalogued as rs747975934; called by muse, mutect2, varscan2
- ADAMTS12 | c.1352G>C p.C451S | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRF5 | c.91A>T p.I31F | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AIF1 | c.404C>G p.T135R | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.28); called by muse, varscan2
- ATP5PD | c.455A>T p.Y152F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.159); called by mutect2, varscan2
- BCLAF3 | c.685A>G p.S229G | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1QTNF6 | c.332T>C p.M111T | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCL19 | c.277-7C>A | Splice Region (SNP) | VAF 66/197 reads (34%) | called by muse, mutect2, varscan2
- CCM2L | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CNGA1 | c.403A>C p.K135Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COPS2 | c.46T>G p.Y16D | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.485); called by muse, varscan2
- DUSP2 | c.650T>C p.F217S | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- EIF3B | c.1256A>C p.H419P | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM221B | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 47/147 reads (32%) | called by muse, mutect2, varscan2
- FUT4 | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAO1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2
- GRM1 | c.2587G>A p.G863S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDX | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, varscan2
- IGHV2-70 | c.199del p.E67Sfs*18 | Frame Shift Del (DEL) | VAF 28/46 reads (61%) | called by pindel, varscan2
- IGHV2-70 | c.179_181del p.Q60del | In Frame Del (DEL) | VAF 22/46 reads (48%) | called by pindel, varscan2
- ITPKB | c.2403G>T p.E801D | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- MUC16 | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC3A | c.301T>A p.S101T | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- MYNN | c.1519T>G p.S507A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.584); called by muse, varscan2
- NLGN4X | c.2215C>T p.H739Y | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.335); called by muse, mutect2
- OGA | c.1899C>A p.N633K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLXNB3 | c.4300T>C p.Y1434H | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2
- PPP1R13B | c.992C>G p.S331* | Nonsense Mutation (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- PTCHD1 | c.2332G>A p.G778S | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SETD5 | c.4066C>T p.P1356S | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLC39A6 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- STAT5B | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TLN2 | c.1654G>C p.A552P | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TLR4 | c.712G>T p.D238Y (on ENST00000355622 / NM_138554.5; = p.D198Y on NM_003266.4) | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TRAF7 | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- WDFY4 | c.697T>A p.C233S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF274 | c.807G>T p.E269D (on ENST00000610905; = p.E164D on NM_016324.3) | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ADAMTS3 | c.2484A>G p.E828= | Silent (SNP) | VAF 7/145 reads (5%) | called by muse, mutect2
- ANK2 | c.7362T>C p.S2454= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- CCDC87 | c.1359C>T p.F453= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs764907584; called by muse, mutect2, varscan2
- CPZ | c.1467G>A p.Q489= (on ENST00000360986 / NM_001014447.3; = p.Q478= on NM_003652.3) | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV59926631; called by muse, mutect2, varscan2
- DNAH5 | c.1257C>T p.S419= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV54244616; called by muse, mutect2, varscan2
- DUS3L | c.1182C>T p.V394= | Silent (SNP) | VAF 47/137 reads (34%) | catalogued as rs368838439; called by muse, mutect2, varscan2
- FAT4 | c.1053G>A p.P351= | Silent (SNP) | VAF 68/134 reads (51%) | catalogued as rs770875689, COSV67882015; called by muse, mutect2, varscan2
- IGHV2-70 | c.126C>G p.T42= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as rs548315389; called by muse, varscan2
- IQCA1 | c.1308C>T p.I436= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- KIZ | c.474C>T p.I158= | Silent (SNP) | VAF 67/132 reads (51%) | called by muse, mutect2, varscan2
- KIZ | c.1237T>C p.L413= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- MMP28 | c.495C>G p.V165= | Silent (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- MOV10L1 | c.1368G>A p.A456= | Silent (SNP) | VAF 27/28 reads (96%) | catalogued as rs199858235, COSV53178862; called by muse, mutect2, varscan2
- NFKB2 | c.2532G>T p.V844= | Silent (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.9270G>A p.R3090= | Silent (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1683C>T p.N561= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as COSV65348182; called by mutect2, varscan2
- RBM25 | c.2067A>G p.L689= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs753041007; called by muse, mutect2, varscan2
- SPTBN5 | c.4269A>G p.Q1423= | Silent (SNP) | VAF 39/126 reads (31%) | called by muse, mutect2, varscan2
- WDR13 | c.183G>A p.L61= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- ZC3H12B | c.960G>C p.L320= | Silent (SNP) | VAF 50/87 reads (57%) | called by muse, mutect2, varscan2
- ACKR1 | chr1:159204747 C>G | 5'Flank (SNP) | VAF 67/411 reads (16%) | called by muse, mutect2, varscan2
- ARHGEF37 | c.*2204T>C | 3'UTR (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- ARRDC4 | c.*1863G>A | 3'UTR (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2
- BEND4 | c.*3159A>G | 3'UTR (SNP) | VAF 12/47 reads (26%) | catalogued as rs1240728368; called by muse, mutect2, varscan2
- BMP2K | c.1951+429T>C | Intron (SNP) | VAF 19/39 reads (49%) | catalogued as rs569210841; called by muse, mutect2, varscan2
- C12orf75 | c.-162C>T | 5'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs1000596843; called by muse, mutect2, varscan2
- C5orf38 | c.404+474A>G | Intron (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- CACNA1D | c.*801C>G | 3'UTR (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- CBR1 | chr21:36069815 C>T | 5'Flank (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- CEP128 | c.1209+407C>T | Intron (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- CHAT | c.*15T>G | 3'UTR (SNP) | VAF 46/307 reads (15%) | called by muse, mutect2, varscan2
- COPS2 | chr15:49155602 A>T | 5'Flank (SNP) | VAF 80/220 reads (36%) | called by muse, varscan2
- CYP3A7 | c.219-20A>C | Intron (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- DDX59 | chr1:200640994 G>A | 3'Flank (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- DGKB | c.2307+810T>C | Intron (SNP) | VAF 13/52 reads (25%) | catalogued as rs955350528, COSV51798061; called by muse, mutect2, varscan2
- DGKI | chr7:137389981 C>G | 3'Flank (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2
- ERFE | c.687+11G>A | Intron (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- ETV1 | c.181+437G>C | Intron (SNP) | VAF 124/392 reads (32%) | called by muse, varscan2
- FAM102A | c.-74T>G | 5'UTR (SNP) | VAF 55/175 reads (31%) | called by muse, mutect2, varscan2
- FBN1 | c.*525C>A | 3'UTR (SNP) | VAF 74/107 reads (69%) | catalogued as rs1205214488; called by muse, mutect2, varscan2
- FHL1 | c.*971A>G | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- GET4 | c.*336T>A | 3'UTR (SNP) | VAF 47/293 reads (16%) | called by muse, mutect2, varscan2
- GLYAT | c.488+108A>T | Intron (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- GPD2 | c.1880+25T>G | Intron (SNP) | VAF 16/33 reads (48%) | catalogued as rs1304075597; called by muse, varscan2
- GPR157 | c.*4035A>G | 3'UTR (SNP) | VAF 31/61 reads (51%) | catalogued as rs1422072327; called by muse, mutect2, varscan2
- GRM2 | c.*405G>A | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- HDAC4 | c.*2150C>T | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- HOMEZ | c.*723C>T | 3'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs913099161; called by mutect2, varscan2
- IGF2BP3 | c.*1562T>A | 3'UTR (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- INPP5A | c.732+74G>A | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- LANCL1 | chr2:210431299 C>T | 3'Flank (SNP) | VAF 3/42 reads (7%) | catalogued as rs1201243125; called by muse, mutect2
- LINC00943 | n.1292C>T | RNA (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- LINC01553 | n.701C>A | RNA (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- LMAN1L | c.175+421G>T | Intron (SNP) | VAF 43/64 reads (67%) | catalogued as COSV59000491; called by muse, mutect2, varscan2
- MC2R | c.-84G>A | 5'UTR (SNP) | VAF 109/179 reads (61%) | called by muse, mutect2, varscan2
- NR2F2 | c.*659G>A | 3'UTR (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- ORMDL3 | c.*616A>C | 3'UTR (SNP) | VAF 71/335 reads (21%) | called by muse, mutect2, varscan2
- PCDHGB6 | c.2418+103T>C | Intron (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- PHF19 | c.*850T>A | 3'UTR (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- PLCB1 | c.2524-6233C>T | Intron (SNP) | VAF 34/114 reads (30%) | called by muse, mutect2, varscan2
- POU3F2 | c.*176T>C | 3'UTR (SNP) | VAF 42/61 reads (69%) | called by muse, mutect2, varscan2
- PRDM1 | c.*1510A>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- PSD | c.*186C>A | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- PSPC1P1 | n.69A>T | RNA (SNP) | VAF 46/47 reads (98%) | called by muse, mutect2, varscan2
- PTGFR | c.*1939G>A | 3'UTR (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- RFLNB | c.*405dup | 3'UTR (INS) | VAF 20/73 reads (27%) | called by mutect2, pindel, varscan2
- RGP1 | c.*2302C>T | 3'UTR (SNP) | VAF 7/65 reads (11%) | catalogued as rs1441625011; called by muse, mutect2, varscan2
- SCN2A | c.*2247_*2250del | 3'UTR (DEL) | VAF 16/28 reads (57%) | called by mutect2, pindel, varscan2
- SLC7A13 | c.*17C>G | 3'UTR (SNP) | VAF 86/191 reads (45%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*149A>G | 3'UTR (SNP) | VAF 26/26 reads (100%) | called by muse, varscan2
- SPOCK3 | c.*866A>C | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2
- TMC8 | c.299-36_299-31dup | Intron (INS) | VAF 31/67 reads (46%) | called by mutect2, varscan2
- TMEM132B | c.*5781T>G | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- TMEM170A | c.*2869G>A | 3'UTR (SNP) | VAF 31/31 reads (100%) | catalogued as rs546787100; called by muse, mutect2, varscan2
- TNPO1 | c.*752G>C | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by mutect2, varscan2
- TRIM33 | c.2768+76G>C | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- TRIO | c.*215G>A | 3'UTR (SNP) | VAF 8/42 reads (19%) | catalogued as rs997916762; called by muse, mutect2, varscan2
- TRPV6 | c.1407-14C>T | Intron (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- TXNIP | c.832-53C>T | Intron (SNP) | VAF 19/304 reads (6%) | called by muse, mutect2
- USP22 | c.*390T>G | 3'UTR (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- ZBTB39 | c.*2187C>G | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- ZBTB39 | c.*1930C>A | 3'UTR (SNP) | VAF 32/53 reads (60%) | called by muse, mutect2, varscan2
- ZBTB39 | c.*1535C>G | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, varscan2
- ZBTB39 | c.*1296C>T | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, varscan2
- ZBTB39 | c.*1295T>A | 3'UTR (SNP) | VAF 17/41 reads (41%) | called by muse, varscan2
- ZBTB39 | c.*1113C>A | 3'UTR (SNP) | VAF 72/141 reads (51%) | called by muse, mutect2, varscan2
- ZBTB39 | c.*553C>G | 3'UTR (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- ZMAT1 | c.121+6763A>C | Intron (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- ZNF681 | c.-24G>A | 5'UTR (SNP) | VAF 43/146 reads (29%) | called by muse, mutect2, varscan2
- ZNF704 | c.*1026C>T | 3'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- ZNF765 | c.*1889A>G | 3'UTR (SNP) | VAF 50/246 reads (20%) | catalogued as rs1347598029; called by muse, mutect2, varscan2
- ZNF773 | c.163+129G>T | Intron (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
